Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A3NF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A3NF-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:
MRN #: 1
Ref Physician:

(Age:)

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Uterus with bilateral adnexa, hysterectomy with bilateral salpingo-oophorectomy:

Tumor Characteristics:

1. Histologic type: Serous carcinoma.
2. Histologic grade: High-grade.
3. Tumor site: Endometrium.
4. Tumor size: 3.5 by 2.5 cm.
5. Myometrial invasion: Tumor extends 1.5 cm into a 2.8 cm thick myometrium (greater than 1/2).
6. Involvement of cervix: Not seen.
7. Extent of involvement of other organs: Not seen.
8. Lymphovascular space invasion: Not seen.

Surgical Margin Status:

1. Margins uninvolved: Uterine serosa, bilateral parametria, cervix.
2. Margins involved: None.

Lymph Node Status:

1. See parts B -D.

Other:

1. Other significant findings: Bilateral ovaries and fallopian tubes without significant pathologic abnormality.
2. pTNM stage: pT1b N1 (FIGO IIIC1).

B. Right paraaortic lymph nodes, excision:

Nine lymph nodes, negative for metastatic disease.

C. Right pelvic lymph nodes, excision:

Ten lymph nodes, negative for metastatic disease.

D. Left pelvic lymph nodes, excision:

One of thirteen lymph nodes positive for metastatic carcinoma.

E. Omentum, excision:

Negative for malignancy.

Reviewed Initials	Date Reviewed: 1/7/12	

ICD-0-3

adenocarcinoma, serous, NOS 8441/3
Site: endometrium c54.1

lw
1/7/12

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: year old female, serous uterine adenocarcinoma on D&C

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Uterus, cervix, bilateral tubes and ovaries
- B. Right paraaortic lymph nodes
- C. Right pelvic lymph nodes
- D. Left pelvic lymph nodes
- E. Omentum

SPECIMEN DATA

GROSS DESCRIPTION:

[page 2 of 2]
The specimen is received in five containers labeled with the patient's name

A. Container A is additionally labeled uterus, cervix, bilateral tubes and ovaries, and contains a 95.7 gram, uterus with attached cervix received with attached right tube and ovary and detached left tube and ovary. The 4.0 cm in length by 4.3 x 3.5 cm uterine corpus is surfaced by pink tan serosa and features surgical punctures on the posterior aspect. The 2.5 cm in length by 3.2 x 3.0 cm uterine cervix is partially surfaced by pink tan glistening ectocervical mucosa and features a central 0.6 cm patent os. The parametrial soft tissues are inked and taken en-face. The endocervical canal is yellow tan cystic and mucoid with the usual folds. The triangular endometrium is remarkable for a 3.5 x 2.5 cm pink tan granular lesion involving primarily the posterior wall. On sectioning, this lesion extends 1.5 cm into a 2.8 cm thick pink tan fibrous myometrium. Normal appearing endometrium is also identified and averages 0.2 cm in thickness. Further inspection of the myometrium reveals focal cystic change. No additional masses are identified.

The right fimbriated fallopian tube is 4.5 cm in length and ranges from 0.4 to 0.7 cm in diameter. It is remarkable for numerous uniloculated paratubal cysts ranging from 0.1 up to 0.7 cm in greatest dimension. These cysts feature smooth inner linings and contain yellow tan serous fluid. The attached yellow tan lobulated ovary is 2.0 x 1.6 x 1.3 cm. The cut surface is yellow tan and fibrous with multiple gray white corpora albicantia.

The left fimbriated fallopian tube is 4.5 cm in length and ranges from 0.5 to 0.7 cm in diameter. It is remarkable for numerous uniloculated paratubal cysts ranging from 0.1 to 0.4 cm in greatest dimension. These cysts feature smooth inner linings and contain yellow tan serous fluid. The attached yellow tan lobulated ovary is 1.5 x 1.1 x 0.6 cm. The cut surface is yellow tan and fibrous with numerous gray white corpora albicantia. Representative sections are submitted in cassettes A1-A17 labeled as follows: A1—right parametrium, en-face; A2—left parametrium, en-face; A3—anterior endo/ectocervix; A4—posterior endo/ectocervix; A5—anterior lower uterine segment; A6—posterior lower uterine segment; A7 to A9—full thickness anterior endometrium to include lesion; A10 to A12—full thickness posterior endometrium to include lesion; A13—most normal appearing endometrium; A14—right fallopian tube; A15—right ovary; A16—left fallopian tube; A17—left ovary, entirely. Additionally, a yellow, green and blue cassette are submitted for genomic research each labeled

B. Container B is additionally labeled right paraaortic lymph nodes and contains a 4.8 x 4.7 x 2.3 cm aggregate of yellow tan fibrofatty soft tissue. On palpation, multiple firm fatty lymph nodes are identified ranging from 0.2 up to 2.0 cm in greatest dimension. They are entirely submitted in cassettes B1-B4 labeled as follows: B1 and B2—three whole possible lymph nodes in each cassette; B3—two whole possible bisected lymph nodes (one inked); B4—one whole possible bisected lymph node.

C. Container C is additionally labeled right nodes and contains a 7.7 x 4.5 x 2.8 cm aggregate of yellow tan fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.2 up to 3.3 cm in greatest dimension. They are entirely submitted in cassettes C1-C7 labeled as follows: C1—four whole possible lymph nodes; C2—three whole possible lymph nodes; C3—one whole possible bisected lymph node; C4 and C5—one whole possible bisected lymph node; C6 and C7—one whole possible bisected lymph node.

D. Container D is additionally labeled left pelvic lymph nodes and contains a 7.0 x 6.0 x 3.0 cm aggregate of yellow tan fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.3 up to 3.0 cm in greatest dimension. They are entirely submitted in cassettes D1-D8 labeled as follows: D1 and D2—four whole possible lymph nodes in each cassette; D3—two whole possible bisected lymph nodes (one inked); D4—one whole possible bisected lymph node; D5 and D6—one whole possible trisected lymph node; D7 and D8—one whole possible trisected lymph node.

E. Container E is additionally labeled omentum and contains a 5.0 x 3.0 x 1.8 cm yellow tan finely lobulated fibrofatty soft tissue consistent with omentum. Sectioning reveals a yellow tan greasy cut surface. No nodules or lesions are identified. Representative sections are submitted in cassettes E1-E4 labeled

Source: NCI Genomic Data Commons file 8fff5bc6-e40f-43ab-bd00-8c00d1642281 (TCGA-AJ-A3NF.7003815D-F09A-46A0-8A8E-E0685A765788.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).